Somatic mutation profile of tumor specimen TCGA-13-1498-01A (aliquot TCGA-13-1498-01A-01W-0549-09) from TCGA case TCGA-13-1498, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.4 years (26,820 days).
Specimen TCGA-13-1498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 912b007c-9a61-482b-8c99-8b8822f331c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1498-10A (Blood Derived Normal), aliquot TCGA-13-1498-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b57f2202-935a-4577-8f0e-4161ecaa025b

The open-access MAF lists 156 somatic variants for this specimen: 116 protein-altering or splice-affecting, 40 silent.
By variant classification: Missense Mutation 85, Silent 40, Nonsense Mutation 11, In Frame Del 5, Frame Shift Del 5, Splice Site 5, Splice Region 3, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 32/49 reads (65%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1433A>T p.D478V | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV100447953; called by muse, mutect2
- ADAM7 | c.139del p.H47Mfs*6 | Frame Shift Del (DEL) | VAF 360/589 reads (61%) | catalogued as COSV51541024, COSV51546369; called by mutect2, pindel, varscan2
- ANAPC16 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV54965762; called by muse, mutect2, varscan2
- APTX | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754156994, COSV58930611; called by muse, mutect2, varscan2
- BMP15 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 119/151 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53142101; called by muse, mutect2, varscan2
- BRD2 | c.1583G>C p.R528P | Missense Mutation (SNP) | VAF 118/383 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66374611; called by muse, mutect2, varscan2
- C1orf226 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV63397059; called by muse, mutect2, varscan2
- C5AR1 | c.969G>T p.L323F | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV61893565; called by muse, mutect2, varscan2
- CACNA2D3 | c.2689A>T p.R897* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs1553623640, COSV55584553; called by muse, mutect2, varscan2
- CADM1 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV59023996; called by muse, mutect2, varscan2
- CAMTA1 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100345328; called by muse, mutect2, varscan2
- CD1B | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV100939159, COSV63803994; called by muse, mutect2, varscan2
- CEACAM7 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 143/351 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as rs1042235201, COSV50075143; called by muse, mutect2, varscan2
- CEP57 | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV57690634; called by muse, mutect2, varscan2
- COL24A1 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65314776; called by muse, mutect2, varscan2
- CRISPLD1 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.531); catalogued as COSV100081439, COSV100081617; called by muse, varscan2
- DCLK1 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 190/437 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV55212857; called by muse, mutect2, varscan2
- DEFB118 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs547430486, COSV53621730; called by muse, mutect2, varscan2
- DGKB | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 258/974 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.257); catalogued as COSV51772918; called by muse, mutect2, varscan2
- FAT4 | c.13052C>T p.P4351L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58710281; called by muse, mutect2, varscan2
- FBN1 | c.7701C>T p.D2567= | Splice Region (SNP) | VAF 160/185 reads (86%) | catalogued as rs368054842; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO43 | c.2069A>G p.N690S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs372427721; called by muse, mutect2
- FOSB | c.342T>G p.S114R | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.766); catalogued as COSV62279299; called by muse, mutect2, varscan2
- FRZB | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166525240, COSV54556202; called by muse, mutect2, varscan2
- GABRG2 | c.888C>A p.S296= (on ENST00000361925 / NM_001375343.1; = p.S256= on NM_000816.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 53/187 reads (28%) | catalogued as COSV62722862; called by muse, mutect2, varscan2
- GAN | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV73721128; called by muse, mutect2
- GPRASP2 | c.1523T>G p.F508C | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59992578; called by muse, mutect2, varscan2
- GRIK5 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760262678, COSV53476516; called by muse, mutect2, varscan2
- HAAO | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54313304; called by muse, mutect2, varscan2
- HACE1 | c.2221G>C p.V741L | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53504279, COSV53508309; called by muse, mutect2, varscan2
- HAP1 | c.1721C>G p.A574G (on ENST00000310778 / NM_001367460.1; = p.A522G on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/225 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as COSV57880919; called by muse, mutect2, varscan2
- HSPA4L | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV99612373; called by muse, mutect2, varscan2
- IKZF4 | c.1176C>G p.I392M | Missense Mutation (SNP) | VAF 168/327 reads (51%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.806); catalogued as COSV100009350, COSV56271844; called by muse, mutect2, varscan2
- IL2RB | c.1278C>A p.D426E | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53428712; called by muse, mutect2, varscan2
- INSR | c.3877G>T p.D1293Y | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV57160448, COSV57173740; called by muse, mutect2, varscan2
- INTS4 | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100489811; called by muse, mutect2
- ITGB2 | c.178A>C p.I60L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs781730372, COSV56614269; called by muse, mutect2, varscan2
- ITPR2 | c.7330A>T p.T2444S | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV67276619; called by muse, mutect2, varscan2
- KIAA1109 | c.12815A>G p.Y4272C | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52694003; called by muse, mutect2, varscan2
- KIF21A | c.4187G>A p.C1396Y (on ENST00000361418 / NM_001378440.1; = p.C1383Y on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs746875582, COSV62778372; called by muse, mutect2, varscan2
- LRRC23 | c.864C>A p.Y288* | Nonsense Mutation (SNP) | VAF 43/155 reads (28%) | catalogued as COSV50392989, COSV99145108; called by muse, mutect2, varscan2
- LRRIQ3 | c.1645A>T p.S549C | Missense Mutation (SNP) | VAF 179/231 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.408); catalogued as COSV63050472; called by muse, mutect2, varscan2
- MAMDC2 | c.1991G>A p.C664Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101015123; called by muse, mutect2
- MAP1A | c.6686C>T p.S2229L | Missense Mutation (SNP) | VAF 123/325 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); catalogued as COSV55813153; called by muse, mutect2, varscan2
- MAP3K5 | c.806+1G>C p.X269_splice | Splice Site (SNP) | VAF 58/198 reads (29%) | catalogued as COSV62892444; called by muse, mutect2, varscan2
- MAST2 | c.1873T>A p.Y625N | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63621557; called by muse, mutect2, varscan2
- MSR1 | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 68/88 reads (77%) | catalogued as rs779064914, COSV100026839, COSV50537910; called by muse, mutect2, varscan2
- MYCBP2 | c.11744T>G p.V3915G (on ENST00000357337; = p.V3953G on NM_015057.5) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100628901, COSV62010571, COSV62031447; called by muse, varscan2
- MYH3 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 152/197 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765585804, COSV56862181; called by muse, mutect2, varscan2
- MYO5C | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776275485, COSV55912451; called by muse, mutect2, varscan2
- NCAN | c.3304T>A p.Y1102N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53059624; called by muse, mutect2, varscan2
- NCKAP5 | c.2945T>A p.I982N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV58477012; called by muse, mutect2, varscan2
- NFS1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 100/202 reads (50%) | catalogued as COSV100931902, COSV65054385; called by muse, mutect2, varscan2
- NOL4 | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 88/112 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV52363193; called by muse, mutect2, varscan2
- NPHS1 | c.2335G>T p.G779* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV62288768, COSV62290009; called by muse, mutect2, varscan2
- NPR1 | c.1938C>A p.G646= | Splice Region (SNP) | VAF 135/534 reads (25%) | catalogued as COSV64118186; called by muse, mutect2, varscan2
- NR5A2 | c.1276A>C p.N426H (on ENST00000367362 / NM_205860.3; = p.N380H on NM_003822.5) | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV52658341; called by muse, mutect2, varscan2
- OLFM2 | c.1129T>G p.C377G | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321392; called by muse, mutect2, varscan2
- OR2G6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100597985; called by muse, mutect2
- OR2J3 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 171/638 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101013533; called by muse, mutect2, varscan2
- OR4C3 | c.523T>A p.F175I | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100167396; called by muse, mutect2, varscan2
- OR5AK2 | c.929A>C p.*310Sext*6 | Nonstop Mutation (SNP) | VAF 47/115 reads (41%) | catalogued as COSV58805444; called by muse, mutect2, varscan2
- PCDHGA5 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV54039307, COSV99543187; called by muse, mutect2, varscan2
- PELP1 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV52592108, COSV52592730; called by muse, mutect2, varscan2
- PKHD1 | c.12130T>G p.L4044V | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV64384128; called by muse, mutect2, varscan2
- PLCG2 | c.3106T>G p.Y1036D | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV63876812; called by muse, mutect2, varscan2
- PLD1 | c.1823A>T p.H608L | Missense Mutation (SNP) | VAF 93/594 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60574492; called by muse, mutect2, varscan2
- PPP1R11 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as COSV54994502; called by muse, mutect2, varscan2
- PRRC2A | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1030886961, COSV100784513; called by muse, mutect2, varscan2
- PRRT2 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.323); catalogued as COSV99569144; called by muse, mutect2, varscan2
- PTCH2 | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 74/321 reads (23%) | catalogued as COSV64713662; called by muse, mutect2, varscan2
- PTPRZ1 | c.1999G>T p.G667* | Nonsense Mutation (SNP) | VAF 89/193 reads (46%) | catalogued as COSV66446115; called by muse, mutect2, varscan2
- RB1CC1 | c.4159G>T p.E1387* | Nonsense Mutation (SNP) | VAF 94/178 reads (53%) | catalogued as COSV50276929; called by muse, mutect2, varscan2
- RFX5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 234/375 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV51837858; called by muse, mutect2, varscan2
- RIF1 | c.3957A>C p.E1319D | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54624807; called by muse, mutect2, varscan2
- RPL15 | c.523G>T p.G175* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV57141068; called by muse, mutect2, varscan2
- RUFY1 | c.2030G>C p.S677T | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV60158585, COSV60163992; called by muse, mutect2, varscan2
- SASH1 | c.2564C>A p.T855N | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100820829; called by muse, mutect2
- SCAF11 | c.1805C>G p.T602R | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV65479270; called by muse, mutect2, varscan2
- SCN3B | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 93/155 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs769173831, COSV54798848, COSV54801419; called by muse, mutect2, varscan2
- SLC10A2 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 106/126 reads (84%) | catalogued as rs780391277, COSV55361877, COSV99807616; called by muse, mutect2, varscan2
- SLC10A6 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56722137, COSV56723163, COSV99907091; called by muse, mutect2
- STAR | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV52418554; called by muse, mutect2, varscan2
- STAU1 | c.928G>C p.E310Q (on ENST00000371856 / NM_001319135.1; = p.E229Q on NM_004602.3) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61462932; called by muse, mutect2, varscan2
- SYNE1 | c.10225G>T p.E3409* (on ENST00000367255 / NM_182961.4; = p.E3416* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 153/169 reads (91%) | catalogued as COSV55080450, COSV55111467; called by muse, mutect2, varscan2
- SYVN1 | c.1522C>T p.R508C (on ENST00000377190 / NM_172230.3; = p.R507C on NM_032431.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs768444718, COSV53697532; called by muse, mutect2, varscan2
- TAS1R2 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs754453014, COSV64746691; called by muse, mutect2, varscan2
- TCP11L2 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54430038; called by muse, mutect2, varscan2
- TEDDM1 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV62380742; called by muse, mutect2, varscan2
- TENM1 | c.3465T>A p.N1155K | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV64444325; called by muse, mutect2, varscan2
- TMEM38B | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65951560; called by muse, mutect2, varscan2
- TNFSF8 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 140/536 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.343); catalogued as COSV56344120; called by muse, mutect2, varscan2
- TRPC6 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as COSV100723376; called by muse, mutect2, varscan2
- USP11 | c.1363G>A p.V455M (on ENST00000218348; = p.V412M on NM_001371072.1) | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54476187; called by muse, mutect2, varscan2
- USP53 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV56797930; called by muse, mutect2, varscan2
- VARS1 | c.3695C>T p.P1232L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1472868752, COSV63305169; called by muse, mutect2, varscan2
- VSTM2A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs548506452, COSV56494837, COSV99043274; called by muse, mutect2, varscan2
- WNT8A | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.677); catalogued as COSV64231799; called by muse, mutect2, varscan2
- ZNF438 | c.1289T>A p.L430Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100061037; called by muse, mutect2
- ZSCAN10 | c.427A>G p.R143G (on ENST00000252463; = p.R198G on NM_032805.3) | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52971049; called by muse, mutect2
- ZSCAN20 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100792458; called by muse, mutect2
- ACP3 | c.1000_1020del p.E334_Y340del | In Frame Del (DEL) | VAF 96/234 reads (41%) | called by mutect2, pindel, varscan2
- EPHA8 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBXL5 | c.1089_1098del p.Q365Ffs*34 | Frame Shift Del (DEL) | VAF 22/28 reads (79%) | called by mutect2, pindel, varscan2
- MAST2 | c.1531_1539del p.D511_E513del | In Frame Del (DEL) | VAF 58/305 reads (19%) | called by mutect2, pindel, varscan2
- MX2 | c.1150-18_1153del p.X384_splice | Splice Site (DEL) | VAF 12/153 reads (8%) | called by mutect2, pindel
- NAA35 | c.43del p.E15Sfs*29 | Frame Shift Del (DEL) | VAF 47/60 reads (78%) | called by pindel, varscan2*
- PARD3 | c.2639_2650del p.P880_G883del | In Frame Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- PCLO | c.3352_3360del p.Q1118_G1120del | In Frame Del (DEL) | VAF 38/168 reads (23%) | called by mutect2, pindel, varscan2
- SHMT2 | c.674_709del p.T225_R236del | In Frame Del (DEL) | VAF 30/110 reads (27%) | called by mutect2, pindel
- SIGLEC6 | c.1150_1151dup p.D385Rfs*4 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by pindel, varscan2
- SMC1B | c.1435_1450del p.L479Cfs*64 | Frame Shift Del (DEL) | VAF 65/89 reads (73%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3755A>G p.H1252R | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by mutect2, varscan2
- SPINK5 | c.397_410+14del p.X133_splice | Splice Site (DEL) | VAF 74/314 reads (24%) | called by mutect2, pindel, varscan2
- ZNF527 | c.495_502del p.S166Wfs*24 | Frame Shift Del (DEL) | VAF 77/205 reads (38%) | called by mutect2, pindel, varscan2
- ADSS2 | c.495C>A p.G165= | Silent (SNP) | VAF 52/162 reads (32%) | catalogued as COSV63696362; called by muse, mutect2, varscan2
- AMER2 | c.1959C>A p.G653= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV63440423; called by muse, mutect2, varscan2
- AMPH | c.1917T>C p.D639= | Silent (SNP) | VAF 191/720 reads (27%) | catalogued as COSV57758328; called by muse, mutect2, varscan2
- BCL9 | c.2670G>T p.S890= | Silent (SNP) | VAF 147/241 reads (61%) | catalogued as COSV52345489, COSV52350476; called by muse, mutect2, varscan2
- CACNA1S | c.604C>T p.L202= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV62944039; called by muse, mutect2, varscan2
- CDH18 | c.99G>A p.V33= | Silent (SNP) | VAF 58/157 reads (37%) | catalogued as COSV56946461, COSV56963170; called by muse, mutect2, varscan2
- ELAVL4 | c.879A>C p.T293= | Silent (SNP) | VAF 130/548 reads (24%) | catalogued as COSV100836470; called by muse, mutect2, varscan2
- FAM53C | c.1092G>T p.V364= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53513089; called by muse, mutect2, varscan2
- FCHSD2 | c.1647G>A p.T549= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs770593555, COSV60814982; called by muse, mutect2, varscan2
- FLRT2 | c.1146G>A p.Q382= | Silent (SNP) | VAF 127/161 reads (79%) | catalogued as COSV58150732; called by muse, mutect2, varscan2
- FUT10 | c.945T>G p.L315= | Silent (SNP) | VAF 71/150 reads (47%) | catalogued as COSV59454389; called by muse, mutect2, varscan2
- GRIN2A | c.561C>A p.V187= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as COSV100407588; called by muse, mutect2
- HAL | c.1737C>T p.V579= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1288618434, COSV54120424; called by muse, mutect2, varscan2
- HNRNPL | c.327G>T p.L109= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV55495597; called by muse, mutect2, varscan2
- IGKV1-27 | c.288C>A p.T96= | Silent (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- INSRR | c.1795C>A p.R599= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV63872477; called by muse, mutect2
- KDM3A | c.2628C>G p.P876= | Silent (SNP) | VAF 127/305 reads (42%) | catalogued as rs776418311, COSV57223334, COSV57225892; called by muse, mutect2, varscan2
- KIRREL1 | c.1371C>T p.T457= | Silent (SNP) | VAF 152/359 reads (42%) | catalogued as COSV63285267; called by muse, mutect2, varscan2
- LAMA4 | c.4374C>T p.H1458= (on ENST00000230538 / NM_001105206.3; = p.H1451= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/237 reads (41%) | catalogued as COSV57905556; called by muse, mutect2, varscan2
- LRRC4C | c.1590T>A p.I530= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV53438574; called by muse, mutect2, varscan2
- NBL1 | c.213C>T p.T71= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV57031542; called by muse, mutect2, varscan2
- NTRK1 | c.1902C>T p.V634= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs148270992; ClinVar: likely benign; called by muse, mutect2, varscan2
- OLFML1 | c.405T>A p.T135= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as COSV61404187; called by muse, mutect2, varscan2
- OR2G6 | c.606C>A p.A202= | Silent (SNP) | VAF 16/366 reads (4%) | catalogued as COSV58574220; called by muse, mutect2
- PAK5 | c.780C>T p.S260= | Silent (SNP) | VAF 139/314 reads (44%) | catalogued as COSV62038612; called by muse, mutect2, varscan2
- PDHB | c.849C>T p.V283= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV57058052; called by muse, mutect2, varscan2
- PDZRN3 | c.1836C>T p.T612= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55216286; called by muse, mutect2, varscan2
- PLXNB1 | c.5949G>C p.L1983= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV56494476; called by muse, mutect2, varscan2
- RP1 | c.3213A>C p.V1071= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99605814; called by muse, mutect2, varscan2
- RSPO2 | c.237A>T p.P79= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV52656592; called by muse, mutect2, varscan2
- RYR2 | c.14133A>T p.G4711= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as COSV63716391; called by muse, mutect2, varscan2
- SCG3 | c.36G>C p.V12= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV55023399; called by muse, mutect2, varscan2
- SEZ6 | c.2088C>A p.G696= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs61657533, COSV100252538; called by muse, mutect2, varscan2
- TBC1D2 | c.2241T>C p.D747= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100579617; called by muse, mutect2, varscan2
- TCAIM | c.1026C>T p.Y342= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as COSV100703120; called by muse, mutect2
- TMEM132D | c.1671G>A p.E557= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs1565957371, COSV67159834, COSV67162571; called by muse, mutect2, varscan2
- TMEM67 | c.2085C>T p.V695= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as COSV60044839; called by muse, mutect2, varscan2
- TOB2 | c.450G>C p.L150= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV59501865; called by muse, mutect2, varscan2
- USP19 | c.3282G>T p.L1094= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV60048787; called by muse, mutect2, varscan2
- WNK1 | c.2409C>A p.G803= | Silent (SNP) | VAF 163/245 reads (67%) | catalogued as COSV60044728, COSV60045954; called by muse, mutect2, varscan2
